Surgical pathology report (de-identified scan), TCGA case TCGA-86-8585, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8585-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

Case ID	Gross Description
[REDACTED]	Lung lobe with the tumor of up to 3.5 x 3 cm in its size. Hilar lymph nodes are soft, hyperemic.

[page 2 of 4]
Microscopic Description	Diagnosis Details
Adenocarcinoma of the lung with solid type of growth, G-3. Seven examined hilar lymph nodes demonstrated reactive changes.	Tumor Features: Unknown, Tumor Extent: Localized, NOS , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

[page 3 of 4]
Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 3 x 0 x 3.5 cm Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 0/7 positive for metastasis (Hilar peribronchial lymph nodes 0/7) Lymphatic invasion: Not specified Venous invasion: Absent Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Left- upper

[page 4 of 4]
[REDACTED] ID	Excision date
[REDACTED]	[REDACTED]
[REDACTED]	[REDACTED]

Source: NCI Genomic Data Commons file c91fecb4-de33-4f5e-8d59-7c71a551fc47 (TCGA-86-8585.6C3D5577-390C-4A80-8C02-DEE4901C2A16.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).